Somatic mutation profile of tumor specimen C3N-01859-01 (aliquot CPT0163910006) from CPTAC case C3N-01859, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-01859-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 776aa48a-e9f2-4a73-acf9-368875890e01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01859-31 (Blood Derived Normal), aliquot CPT0163950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc41975-c092-44a3-9727-e8231ba278b3

The open-access MAF lists 280 somatic variants for this specimen: 192 protein-altering or splice-affecting, 50 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 50, RNA 12, Nonsense Mutation 12, Intron 11, 5'UTR 7, Frame Shift Del 4, 3'UTR 3, 3'Flank 3, Splice Site 3, 5'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MPZ | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.47); catalogued as rs121913596, CM102293, CM992928, COSV60668061; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 241/461 reads (52%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55944857; called by muse, mutect2
- ACER1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774677805, COSV56834515; called by muse, mutect2, varscan2
- ANGPTL6 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.1); catalogued as rs757435327; called by muse, mutect2, varscan2
- ANK3 | c.10369C>T p.R3457C | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs777814492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP15 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs747712329, COSV54508558; called by muse, mutect2, varscan2
- ATP1A2 | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 129/372 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100767888; called by muse, mutect2, varscan2
- ATP9A | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs756678556; called by muse, mutect2, varscan2
- C6orf58 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs770899693; called by muse, mutect2, varscan2
- CADPS | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1190512729; called by muse, mutect2, varscan2
- CAPN8 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1389121191, COSV64815493; called by muse, mutect2, varscan2
- CD22 | c.99C>G p.Y33* | Nonsense Mutation (SNP) | VAF 30/191 reads (16%) | catalogued as COSV50055741; called by muse, mutect2, varscan2
- CDCA7 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs964226690; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>A p.X50_splice | Splice Site (SNP) | VAF 125/252 reads (50%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- CLCN2 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 60/624 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325778309, COSV55599415; called by muse, mutect2
- COPG2 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as rs201593149; called by muse, mutect2, varscan2
- CSMD1 | c.3454C>A p.L1152M (on ENST00000520002; = p.L1151M on NM_033225.6) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100141940; called by muse, mutect2, varscan2
- CSMD3 | c.8614C>A p.P2872T (on ENST00000297405 / NM_001363185.1; = p.P2703T on NM_052900.3) | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV52191919; called by muse, mutect2, varscan2
- CTRB2 | c.775A>T p.I259F | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs200309186; called by muse, mutect2, varscan2
- CUBN | c.7385C>T p.T2462I | Missense Mutation (SNP) | VAF 64/394 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs748421111; called by muse, mutect2, varscan2
- CYP11B2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 110/487 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs1443503538, COSV100011453; called by muse, varscan2
- DCC | c.3977C>T p.A1326V | Missense Mutation (SNP) | VAF 93/511 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.412); catalogued as rs1299639149; called by muse, mutect2, varscan2
- DPP10 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490235143; called by muse, mutect2
- DSTYK | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs143877075; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs1480176971; called by muse, mutect2, varscan2
- ELL | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs758636936, COSV53214220; called by muse, mutect2, varscan2
- FAM133A | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs865841298, COSV59075939; called by muse, mutect2, varscan2
- FBN3 | c.8236G>A p.E2746K | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs780590806, COSV53664292; called by muse, mutect2, varscan2
- GAD2 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs768167687, COSV52153653; called by muse, mutect2, varscan2
- GPAA1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs782651271; called by muse, mutect2, varscan2
- GRID2 | c.1490del p.G497Efs*13 | Frame Shift Del (DEL) | VAF 32/169 reads (19%) | catalogued as COSV56203533; called by mutect2, pindel, varscan2
- IFNW1 | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 124/228 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV66522087; called by muse, mutect2, varscan2
- KDM5C | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782288948, COSV64769116; called by muse, mutect2, varscan2
- KIF3C | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs377280135; called by muse, mutect2, varscan2
- KRT85 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 83/507 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.191); catalogued as rs370269453; called by muse, mutect2, varscan2
- LGR6 | c.515A>G p.N172S (on ENST00000367278 / NM_001017403.1; = p.N120S on NM_021636.3) | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376357186; called by muse, mutect2, varscan2
- MLIP | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.393); catalogued as rs1228325991; called by muse, mutect2, varscan2
- NFIL3 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs368413458; called by muse, mutect2, varscan2
- NLRP10 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.219); catalogued as rs1213916582, COSV60779140; called by muse, mutect2, varscan2
- NLRP3 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV60226249; called by muse, mutect2, varscan2
- OPRPN | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV68192639; called by muse, mutect2, varscan2
- OR5M10 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV101595870, COSV73242389; called by muse, mutect2, varscan2
- PAPSS1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374190069, COSV54493341; called by muse, mutect2, varscan2
- PCDHGA7 | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as COSV54029028; called by muse, mutect2, varscan2
- PDCL3 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV51808640, COSV99959706; called by muse, mutect2, varscan2
- PDYN | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV54102969; called by muse, mutect2, varscan2
- PEG3 | c.3368C>G p.T1123R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV55635879; called by muse, mutect2, varscan2
- PGBD5 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58410718; called by muse, mutect2, varscan2
- PLEKHA1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs763713208, COSV64569071; called by muse, mutect2
- RAP1GDS1 | c.402G>C p.Q134H (on ENST00000408927 / NM_001100427.2; = p.Q135H on NM_021159.5) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52783985; called by muse, mutect2, varscan2
- RFX3 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs766398506; called by muse, varscan2
- RNF113B | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV57435673; called by muse, mutect2, varscan2
- RTN4R | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755446506, COSV50380807; called by muse, mutect2, varscan2
- SDF2 | c.11T>A p.V4E | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99897832; called by muse, varscan2
- SEMG1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.981); catalogued as rs199781597; called by muse, mutect2, varscan2
- SHMT2 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866649122; called by muse, mutect2, varscan2
- SI | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52306582; called by muse, mutect2, varscan2
- SIGLEC12 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 78/389 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs1361490493, COSV52465500; called by muse, mutect2, varscan2
- SLC17A6 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as COSV54138453; called by muse, mutect2, varscan2
- SLC26A7 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605389; called by muse, mutect2, varscan2
- SPHK2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1315911887, COSV55342380; called by muse, mutect2, varscan2
- SRCAP | c.5414C>A p.T1805N | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs1161028209; called by muse, mutect2, varscan2
- TNRC18 | c.7513C>T p.P2505S | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs753919497, COSV60307352; called by muse, mutect2, varscan2
- TRHDE | c.2149C>G p.R717G | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53837299; called by muse, mutect2, varscan2
- TRIM10 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV64989083; called by muse, mutect2, varscan2
- TRIM72 | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs776598239; called by muse, mutect2, varscan2
- TWIST1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.441); catalogued as rs920859481; called by muse, mutect2, varscan2
- USH2A | c.4483G>T p.G1495* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as CM1211752; called by muse, mutect2, varscan2
- XXYLT1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 195/417 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs1190509457; called by muse, mutect2, varscan2
- ZNF334 | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100749019; called by muse, mutect2, varscan2
- ZNF385B | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs371958237; called by muse, varscan2
- ZNF471 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100340816; called by muse, mutect2, varscan2
- ZNF540 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs200091894; called by muse, mutect2, varscan2
- ZNF773 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587765; called by muse, mutect2, varscan2
- ZNF804A | c.3262C>A p.Q1088K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as COSV56434009; called by muse, mutect2, varscan2
- ZNF99 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1175909307; called by muse, mutect2, varscan2
- ADAMTS1 | c.143_152del p.D48Gfs*10 | Frame Shift Del (DEL) | VAF 15/158 reads (9%) | called by mutect2, pindel
- ANO5 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARFGEF2 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 90/513 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGAP9 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID3B | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASCL3 | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ATP2C2 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXIN1 | c.2480T>A p.V827E | Missense Mutation (SNP) | VAF 133/309 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNB2 | c.1535C>T p.S512F (on ENST00000324631 / NM_201596.3; = p.S457F on NM_000724.4) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CCDC39 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CCNT1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNGB1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- COPB2 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CORO2B | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYLC1 | c.1369G>T p.G457C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DDI1 | c.519C>A p.S173R | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIO2 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 41/354 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPPA4 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- DPY19L3 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- EBF1 | c.1459A>G p.S487G | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFHC1 | c.1278G>T p.L426= | Splice Region (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- EPB41L3 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESR1 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ETS1 | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F11 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- FAM47C | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FAM89A | c.203del p.G68Afs*158 | Frame Shift Del (DEL) | VAF 43/369 reads (12%) | called by pindel, varscan2*
- FGF16 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 96/173 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FMN2 | c.1415A>G p.D472G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMNL3 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- FSIP2 | c.10145T>A p.L3382H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRIP1 | c.2233G>T p.E745* (on ENST00000359742 / NM_001379345.1; = p.E693* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 128/284 reads (45%) | called by muse, mutect2, varscan2
- HHIPL1 | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HNF1A | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGKV1D-33 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- IL12RB1 | c.613del p.A205Pfs*37 | Frame Shift Del (DEL) | VAF 81/588 reads (14%) | called by mutect2, pindel, varscan2
- ITGA4 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IZUMO3 | c.673G>T p.G225W (on ENST00000543880 / NM_001365008.2; = p.G219W on NM_001271706.1) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- KCNA1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KCNA10 | c.1262C>G p.T421S | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KHDC1L | c.61C>G p.H21D | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- L1CAM | c.2432-4C>T | Splice Region (SNP) | VAF 77/132 reads (58%) | called by muse, mutect2, varscan2
- MAP1S | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 45/324 reads (14%) | called by muse, mutect2, varscan2
- MAP3K20 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K21 | c.2984A>G p.H995R | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MCFD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MDGA2 | c.720G>A p.W240* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- ME2 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MUC4 | c.9719C>T p.S3240L | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MUC4 | c.8039C>T p.S2680L | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MYH4 | c.4652C>A p.A1551E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYOCD | c.1370dup p.I458Dfs*7 | Frame Shift Ins (INS) | VAF 33/98 reads (34%) | called by pindel, varscan2
- MYT1L | c.1178C>A p.S393* | Nonsense Mutation (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- NAV3 | c.3812C>T p.S1271F | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, varscan2
- NKTR | c.1477C>A p.H493N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NOX3 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP210L | c.2419A>T p.R807W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- OR2A5 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR2M5 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by mutect2, varscan2
- OR52E8 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PCDHB9 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 201/552 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PCNT | c.3898G>T p.E1300* | Nonsense Mutation (SNP) | VAF 39/323 reads (12%) | called by muse, mutect2, varscan2
- PDE1A | c.1430C>G p.T477R | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); called by mutect2, varscan2
- PDE4DIP | c.3291C>A p.S1097R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); called by mutect2, varscan2
- PEG3 | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PKHD1L1 | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLCL1 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLXDC2 | c.452A>T p.N151I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PNMA2 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PNPLA6 | c.946G>T p.V316L (on ENST00000414982 / NM_001166111.2; = p.V268L on NM_006702.5) | Missense Mutation (SNP) | VAF 85/533 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POM121L2 | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PPP4R1 | c.1651A>T p.R551* (on ENST00000400556 / NM_001042388.3; = p.R534* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- PRDM5 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PRSS23 | c.229A>C p.T77P | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- RAB3IP | c.1414T>C p.F472L (on ENST00000550536 / NM_175623.4; = p.F456L on NM_022456.5) | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAI1 | c.3724C>G p.R1242G | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RBCK1 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- REV1 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRNAD1 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- RYR2 | c.13859A>T p.Q4620L | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SERPINC1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SIRPB2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SKA1 | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SLC6A12 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLC6A15 | c.1187C>G p.S396* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- SLC9A2 | c.536G>C p.W179S | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLIT1 | c.1719C>A p.S573R | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SMARCD1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SORCS2 | c.2216A>C p.D739A | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2
- SPZ1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- STAP2 | c.1192A>T p.R398W (on ENST00000594605 / NM_001013841.2; = p.R444W on NM_017720.3) | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STARD9 | c.4439A>G p.H1480R | Missense Mutation (SNP) | VAF 127/305 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STON2 | c.1605C>G p.I535M (on ENST00000649389 / NM_001366849.2; = p.I478M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SUCLG2 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SYNGAP1 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TAF1L | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TLE5 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TMED8 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOX | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TOX2 | c.1309C>T p.P437S (on ENST00000358131 / NM_001098798.2; = p.P413S on NM_032883.3) | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRGC1 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 28/747 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2
- TRPC4 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSGA10IP | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBQLNL | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, varscan2
- UNC79 | c.6832G>C p.D2278H (on ENST00000393151 / NM_001346218.2; = p.D2101H on NM_020818.5) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP36 | c.1884G>T p.Q628H | Missense Mutation (SNP) | VAF 203/365 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- USP40 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- VN1R1 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- VWA8 | c.1213-1G>T p.X405_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- ZNF385B | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, varscan2
- ZNF600 | c.1144G>T p.G382* | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- ZNF784 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF804A | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.181); called by muse, mutect2
- ANO5 | c.426C>G p.T142= | Silent (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.4446C>T p.I1482= | Silent (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- ATP9B | c.2928C>T p.F976= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs747137781; called by muse, mutect2, varscan2
- C6orf118 | c.570C>G p.A190= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV57813134; called by muse, mutect2, varscan2
- CACNB2 | c.93C>T p.P31= | Silent (SNP) | VAF 66/368 reads (18%) | catalogued as COSV99996124; called by muse, mutect2, varscan2
- CATSPERD | c.348C>G p.V116= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV101062760; called by muse, mutect2, varscan2
- CCT6B | c.1392A>C p.V464= | Silent (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.750G>T p.R250= | Silent (SNP) | VAF 21/89 reads (24%) | called by mutect2, varscan2
- COL4A3 | c.3525G>A p.L1175= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- DNAH6 | c.8560T>C p.L2854= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1407681353; called by muse, mutect2, varscan2
- DNHD1 | c.10221T>C p.Y3407= | Silent (SNP) | VAF 89/207 reads (43%) | called by muse, mutect2, varscan2
- DPP6 | c.273G>A p.R91= (on ENST00000377770 / NM_001364500.2; = p.R29= on NM_001936.5) | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs1563684881, COSV100128886; called by muse, mutect2, varscan2
- DRC7 | c.2307G>T p.A769= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV61055042; called by muse, mutect2
- EYS | c.3810C>T p.V1270= | Silent (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- FAM53B | c.1173G>T p.A391= | Silent (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- GMPPA | c.267A>G p.L89= | Silent (SNP) | VAF 29/181 reads (16%) | called by muse, mutect2, varscan2
- HEATR5A | c.366G>A p.L122= | Silent (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- IGDCC4 | c.3663G>A p.E1221= | Silent (SNP) | VAF 58/147 reads (39%) | called by muse, mutect2, varscan2
- KCNH2 | c.9G>T p.V3= | Silent (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- KNDC1 | c.228G>A p.Q76= | Silent (SNP) | VAF 92/577 reads (16%) | catalogued as rs1234768986; called by muse, varscan2
- LRFN1 | c.480C>T p.F160= | Silent (SNP) | VAF 60/398 reads (15%) | catalogued as rs374526893; called by muse, mutect2, varscan2
- MACF1 | c.801C>A p.V267= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- NAV3 | c.3888C>T p.G1296= | Silent (SNP) | VAF 78/573 reads (14%) | called by muse, varscan2
- NPTX2 | c.378G>A p.Q126= | Silent (SNP) | VAF 181/585 reads (31%) | called by muse, mutect2, varscan2
- OR2A5 | c.339C>G p.L113= | Silent (SNP) | VAF 46/247 reads (19%) | called by muse, mutect2, varscan2
- OR2H2 | c.672G>C p.L224= | Silent (SNP) | VAF 49/302 reads (16%) | called by mutect2, varscan2
- OR4K2 | c.72G>A p.Q24= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- OR6T1 | c.171A>T p.I57= | Silent (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- OXCT1 | c.264C>T p.V88= | Silent (SNP) | VAF 26/237 reads (11%) | catalogued as rs1243928672; called by muse, mutect2, varscan2
- PIGO | c.1866G>A p.L622= | Silent (SNP) | VAF 93/387 reads (24%) | called by muse, mutect2, varscan2
- PLS1 | c.927C>A p.A309= | Silent (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- PLXNC1 | c.93C>T p.P31= | Silent (SNP) | VAF 164/489 reads (34%) | called by muse, mutect2, varscan2
- POU3F3 | c.483C>G p.G161= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- PPIL1 | c.342G>C p.V114= | Silent (SNP) | VAF 104/260 reads (40%) | called by muse, mutect2, varscan2
- PTPRM | c.378G>A p.G126= | Silent (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- RAI1 | c.3723G>A p.L1241= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- RGPD3 | c.3732G>A p.G1244= | Silent (SNP) | VAF 59/834 reads (7%) | catalogued as rs760219195; called by muse, mutect2
- ROS1 | c.5649T>C p.H1883= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs368278112; called by muse, varscan2
- SH2D2A | c.918G>A p.V306= | Silent (SNP) | VAF 36/141 reads (26%) | called by muse, mutect2, varscan2
- SLC17A6 | c.75C>A p.G25= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- SLC4A1AP | c.1845C>T p.S615= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- SULF1 | c.1458G>T p.R486= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV99483025; called by muse, mutect2, varscan2
- SUV39H2 | c.414G>A p.Q138= (on ENST00000354919 / NM_001193424.2; = p.Q78= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- TGFBRAP1 | c.93G>A p.E31= | Silent (SNP) | VAF 141/284 reads (50%) | called by muse, mutect2, varscan2
- TMEM176A | c.702A>C p.G234= | Silent (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1326C>T p.S442= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- WDR97 | c.1812C>T p.I604= | Silent (SNP) | VAF 130/323 reads (40%) | catalogued as rs1043614662; called by muse, mutect2, varscan2
- WNT5B | c.513C>T p.F171= | Silent (SNP) | VAF 86/534 reads (16%) | catalogued as rs748089058; called by muse, mutect2, varscan2
- ZBED9 | c.1005G>A p.K335= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV71729730; called by muse, mutect2, varscan2
- ZFHX4 | c.612A>G p.P204= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as rs759534883; called by muse, mutect2, varscan2
- AC005863.1 | n.172C>A | RNA (SNP) | VAF 138/286 reads (48%) | catalogued as rs757101076; called by muse, mutect2, varscan2
- AC021218.1 | n.945C>G | RNA (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- APOL2 | c.-27C>T | 5'UTR (SNP) | VAF 116/315 reads (37%) | catalogued as rs781262750; called by muse, mutect2, varscan2
- APOL2 | c.-28G>T | 5'UTR (SNP) | VAF 118/316 reads (37%) | called by muse, mutect2, varscan2
- BX119917.1 | n.60C>G | RNA (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- CARMIL1 | chr6:25279102 C>G | 5'Flank (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- CRACR2B | c.277+76C>G | Intron (SNP) | VAF 16/345 reads (5%) | catalogued as rs1401398861, COSV100352014; called by muse, mutect2
- CTSL3P | n.506C>T | RNA (SNP) | VAF 98/220 reads (45%) | catalogued as rs745495542; called by muse, mutect2, varscan2
- CYP2G1P | n.2061G>A | RNA (SNP) | VAF 17/263 reads (6%) | catalogued as rs1172524027; called by muse, mutect2
- DUOXA1 | chr15:45117720 del C | 3'Flank (DEL) | VAF 58/154 reads (38%) | called by mutect2, pindel, varscan2
- EHMT2 | c.2344-9C>T | Intron (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- EYS | c.1767-6440T>C | Intron (SNP) | VAF 11/92 reads (12%) | called by mutect2, varscan2
- FMN2 | c.-110dup | 5'UTR (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- H2BC18 | c.378-9364G>A | Intron (SNP) | VAF 43/148 reads (29%) | catalogued as rs587631127; called by muse, mutect2, varscan2
- HSP90B3P | n.866A>C | RNA (SNP) | VAF 7/185 reads (4%) | called by muse, mutect2
- IMPA1 | c.-25+402G>A | Intron (SNP) | VAF 42/351 reads (12%) | catalogued as rs967948498; called by muse, mutect2, varscan2
- KLF10 | c.-26T>C | 5'UTR (SNP) | VAF 105/384 reads (27%) | called by muse, mutect2, varscan2
- LGMN | c.*140C>A | 3'UTR (SNP) | VAF 39/125 reads (31%) | called by muse, mutect2, varscan2
- LINC00602 | n.767C>T | RNA (SNP) | VAF 24/164 reads (15%) | catalogued as rs1036055891; called by muse, mutect2, varscan2
- LINC01591 | n.437G>C | RNA (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- LINC02693 | n.845G>C | RNA (SNP) | VAF 36/272 reads (13%) | called by muse, varscan2
- LINC02716 | n.262C>T | RNA (SNP) | VAF 36/213 reads (17%) | called by muse, mutect2, varscan2
- MCOLN1 | c.681-50C>T | Intron (SNP) | VAF 11/91 reads (12%) | catalogued as rs373696018; called by muse, mutect2, varscan2
- NDUFA11 | chr19:5893212 C>T | 3'Flank (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- NSUN3 | c.-9A>C | 5'UTR (SNP) | VAF 37/296 reads (13%) | called by muse, mutect2, varscan2
- NTN5 | chr19:48673191 G>A | 5'Flank (SNP) | VAF 101/314 reads (32%) | called by muse, mutect2, varscan2
- ODAPH | c.67+433A>G | Intron (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- REG3G | c.*1G>A | 3'UTR (SNP) | VAF 13/115 reads (11%) | catalogued as COSV99709278; called by muse, mutect2, varscan2
- RGS6 | c.*12G>T | 3'UTR (SNP) | VAF 57/167 reads (34%) | called by muse, mutect2, varscan2
- SERTAD4 | c.-18+883G>A | Intron (SNP) | VAF 35/206 reads (17%) | catalogued as rs1408955096; called by muse, mutect2, varscan2
- SHISAL2B | c.192-1394A>T | Intron (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- SLC66A1L | n.313C>A | RNA (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- SMPX | c.*14+3818G>A | Intron (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- TTYH1 | c.305+191A>G | Intron (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- VN1R10P | n.684C>A | RNA (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- VSTM2B | c.-39G>T | 5'UTR (SNP) | VAF 42/227 reads (19%) | catalogued as rs1555747222; called by muse, mutect2, varscan2
- WASH2P | chr2:113600099 C>T | 3'Flank (SNP) | VAF 55/722 reads (8%) | called by muse, mutect2, varscan2
- ZNF653 | c.-6G>A | 5'UTR (SNP) | VAF 21/109 reads (19%) | catalogued as rs1306614369; called by muse, mutect2, varscan2
